Somatic mutation profile of tumor specimen TCGA-24-2019-01A (aliquot TCGA-24-2019-01A-02W-0722-08) from TCGA case TCGA-24-2019, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.6 years (17,009 days).
Specimen TCGA-24-2019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97c8ec1c-c9f4-4a2c-bc7b-d34b9ea52803.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2019-10A (Blood Derived Normal), aliquot TCGA-24-2019-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efed434-a7c5-4941-8b4d-f4a6c04c1e69

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, Frame Shift Ins 3, Nonsense Mutation 2, RNA 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 83/105 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM103212, COSV52661257, COSV52760307, COSV52829354; called by muse, mutect2, varscan2
- ANKRD11 | c.5920C>T p.P1974S | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1395778977, COSV56366728; called by muse, mutect2, varscan2
- AOX1 | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs1456075706, COSV53496677; called by muse, mutect2, varscan2
- BEND2 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 52/272 reads (19%) | catalogued as COSV66216378; called by muse, mutect2, varscan2
- CDH2 | c.814T>A p.W272R | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV52289270; called by muse, mutect2, varscan2
- DNAH2 | c.5417G>A p.G1806D | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66723052; called by muse, mutect2, varscan2
- DNM2 | c.1936G>T p.D646Y (on ENST00000355667 / NM_001005360.3; = p.D642Y on NM_004945.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100118141, COSV58959919; called by muse, varscan2
- FASTKD1 | c.665C>G p.T222S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV70007105; called by muse, mutect2, varscan2
- FAXDC2 | c.367-1G>A p.X123_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV58173348; called by muse, mutect2
- GPR151 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as rs1181707597, COSV57039876; called by muse, mutect2, varscan2
- KIF4A | c.3179G>A p.G1060D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV65544693; called by muse, varscan2
- MITF | c.1109G>T p.R370L (on ENST00000448226 / NM_006722.3; = p.R270L on NM_000248.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV58833883; called by muse, mutect2, varscan2
- MUC3A | c.8312G>T p.G2771V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100115501, COSV60228019; called by muse, varscan2
- OGFRL1 | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 2/24 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV64971770; called by mutect2, varscan2
- PC | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137879213; called by mutect2, varscan2
- PCDH1 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs566915735, COSV54617145; called by muse, mutect2, varscan2
- PCGF1 | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.213); catalogued as COSV52043754; called by muse, mutect2, varscan2
- POU5F2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1266630516, COSV67939807; called by muse, mutect2, varscan2
- RCOR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56849465; called by muse, mutect2
- SEC16A | c.6457C>T p.P2153S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1377073825, COSV51534926; called by muse, mutect2
- SHQ1 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100344858, COSV57767325; called by muse, mutect2, varscan2
- SLC44A5 | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV63769806; called by mutect2, varscan2
- TAF2 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1440582191, COSV65419598; called by muse, mutect2, varscan2
- TEX2 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99367561; called by muse, mutect2, varscan2
- TGFB2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376159002; ClinVar: uncertain significance; called by muse, mutect2
- THSD7B | c.2810G>T p.C937F | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55650295, COSV55715288; called by muse, mutect2, varscan2
- TMEM241 | c.486G>A p.G162= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as rs1457033543, COSV101271789; called by muse, mutect2, varscan2
- UGT2B10 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs200957276, COSV55319496; called by muse, mutect2, varscan2
- UGT2B15 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100592472; called by muse, mutect2, varscan2
- WDR76 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs367740612; called by muse, varscan2
- ZDBF2 | c.3254A>G p.E1085G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV65628317; called by muse, mutect2, varscan2
- ZIC3 | c.1019C>G p.A340G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV54975633; called by muse, mutect2, varscan2
- ZMAT1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV65658572; called by muse, mutect2, varscan2
- ARHGAP28 | c.1474C>A p.Q492K (on ENST00000383472 / NM_001366230.1; = p.Q333K on NM_001010000.3) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.287); called by muse, mutect2
- ARHGEF39 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by mutect2, varscan2
- CREBBP | c.6257T>A p.V2086E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAREM1 | c.2067T>A p.S689R (on ENST00000269209 / NM_001242409.2; = p.S688R on NM_022751.3) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.053); called by mutect2, varscan2
- PHLDB1 | c.465dup p.Y156Lfs*39 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by pindel, varscan2
- PRMT9 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2
- SREBF2 | c.978dup p.K327Qfs*10 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by pindel, varscan2
- UBA1 | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YY1AP1 | c.929_930delinsGGT p.K310Rfs*26 (on ENST00000295566 / NM_139118.2; = p.K253Rfs*26 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/222 reads (8%) | called by pindel, varscan2*
- AIMP2 | c.384G>T p.P128= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV52241545; called by muse, mutect2
- ATP2A2 | c.2658T>C p.D886= | Silent (SNP) | VAF 51/215 reads (24%) | catalogued as COSV57875944; called by muse, mutect2, varscan2
- CHRNB3 | c.594C>T p.N198= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs544144336, COSV51494038; called by muse, varscan2
- FGF10 | c.79C>T p.L27= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as rs1325781485, COSV52941184; called by muse, mutect2, varscan2
- MRGPRX2 | c.465C>T p.A155= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV61674597; called by muse, mutect2, varscan2
- OPN1MW | c.879C>A p.A293= | Silent (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- TBC1D3B | c.423C>T p.H141= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as rs1199028270; called by muse, varscan2
- TFE3 | c.1089C>T p.N363= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs201808352, COSV59948312; called by muse, mutect2, varscan2
- AC074085.2 | n.329G>A | RNA (SNP) | VAF 65/246 reads (26%) | catalogued as rs1044444646; called by muse, mutect2, varscan2
- KIR3DX1 | n.68C>T | RNA (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99683714; called by muse, mutect2
